Somatic mutation profile of tumor specimen TCGA-2J-AABK-01A (aliquot TCGA-2J-AABK-01A-31D-A40W-08) from TCGA case TCGA-2J-AABK, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.7 years (26,188 days).
Specimen TCGA-2J-AABK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86b3ffc4-f0cf-4925-a55b-4fa78f970624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABK-10A (Blood Derived Normal), aliquot TCGA-2J-AABK-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a80d58c-19a6-4517-a7fc-8ef725a1e678

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 4, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/228 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SDR9C7 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 56/546 reads (10%) | catalogued as rs774363396, COSV53288443; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 16/122 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs876660333, CM942122, COSV52701102, COSV52773741, COSV52787833, COSV53259929; ClinVar: uncertain significance; called by muse, mutect2
- ADGRG4 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99794208; called by muse, mutect2, varscan2
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 16/478 reads (3%) | catalogued as COSV58613404; called by muse, mutect2
- BIRC6 | c.13090C>T p.L4364F | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101427778; called by muse, mutect2
- BRAF | c.1505G>C p.R502T (on ENST00000288602 / NM_001374244.1; = p.R462T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/468 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV56176801, COSV56275998, COSV56383150; called by muse, mutect2, varscan2
- C12orf66 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs759204574, COSV100320515; called by muse, mutect2
- CACNA1S | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558090893, COSV100754592; called by muse, mutect2, varscan2
- CCDC114 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs1205425414, COSV100196274; called by muse, mutect2
- CCL26 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 41/390 reads (11%) | catalogued as rs200686147, COSV50013634; called by muse, mutect2, varscan2
- CEBPZ | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV99135395; called by muse, mutect2
- CRNN | c.1173C>A p.S391R | Missense Mutation (SNP) | VAF 46/612 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.844); catalogued as COSV99663888; called by muse, mutect2
- DOP1A | c.4166A>G p.K1389R | Missense Mutation (SNP) | VAF 29/599 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV99380791; called by muse, mutect2
- IQGAP1 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184853; called by muse, mutect2, varscan2
- KDM5A | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV101238583; called by muse, mutect2
- MLLT11 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100927355; called by muse, mutect2
- MYH4 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1029456820, COSV99700257; called by muse, mutect2
- NLRP13 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100737998, COSV100738147; called by muse, mutect2
- PROP1 | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as COSV100383597; called by muse, mutect2
- RNF213 | c.11716G>A p.G3906R | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs1025831748, COSV60389125; called by muse, mutect2
- SORCS1 | c.1940C>T p.T647I | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs533738961, COSV53853029, COSV53897383; called by muse, mutect2, varscan2
- USP39 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 46/698 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1480469963, COSV100083586; called by muse, mutect2
- VARS1 | c.1467G>A p.E489= | Splice Region (SNP) | VAF 17/303 reads (6%) | catalogued as rs752386634, COSV100989858; called by muse, mutect2
- WDR6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 56/535 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs981114396, COSV100556118; called by muse, mutect2, varscan2
- AHNAK | c.8571C>T p.G2857= | Silent (SNP) | VAF 34/822 reads (4%) | catalogued as COSV99945358; called by muse, mutect2
- CD163L1 | c.1830C>T p.D610= | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as rs140225151; called by muse, mutect2
- COL6A6 | c.5043C>T p.D1681= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV100649730; called by muse, mutect2
- CPSF1 | c.3129G>A p.P1043= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs782129628, COSV100450144; called by muse, mutect2
- EPHB2 | c.612C>A p.G204= | Silent (SNP) | VAF 27/182 reads (15%) | catalogued as COSV101006720, COSV101006802; called by muse, mutect2, varscan2
- PNMA8B | c.339C>T p.D113= | Silent (SNP) | VAF 62/656 reads (9%) | catalogued as rs1471611523, COSV66536138; called by muse, mutect2
- SOHLH2 | c.339G>A p.G113= | Silent (SNP) | VAF 20/648 reads (3%) | catalogued as COSV100499215; called by muse, mutect2
- TUBA1C | c.912A>G p.K304= | Silent (SNP) | VAF 50/506 reads (10%) | catalogued as COSV99988613; called by muse, mutect2
- VPS13C | c.9921A>T p.L3307= (on ENST00000644861 / NM_020821.3; = p.L3264= on NM_017684.5) | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV99826845; called by muse, mutect2
- ZC3H12A | c.1425A>T p.G475= | Silent (SNP) | VAF 54/401 reads (13%) | catalogued as COSV100897632; called by muse, mutect2, varscan2
- DSCR4 | n.136G>A | RNA (SNP) | VAF 18/219 reads (8%) | catalogued as rs374848395; called by muse, mutect2
